Gene-level copy-number profile of tumor specimen TCGA-23-2077-01A from TCGA case TCGA-23-2077, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 45.3 years (16,552 days).
Specimen TCGA-23-2077-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.ce80ec8f-3643-4ca1-9907-05aead9e9eab.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-2077-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 410 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/270917d8-6eef-4164-a28a-9e14f3f75d62

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,293; copy number 1: 22,255; copy number 2: 24,877; copy number 3: 9,190; copy number 4: 1,585; copy number 5: 988; copy number 7: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-23-2077-01A-01D-0663-01): tumor purity 0.47, ploidy 6.14, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 772 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:15,828,232–15,828,669, 1 gene (within-gene range 0–2): AL450998.1.
- chr3:9,100,803–9,104,078, 1 gene (within-gene range 0–2): AC037193.1.
- chr5:60,743,563–60,945,073, 5 genes: KRT8P31, ELOVL7, ERCC8, GNL3LP1, ERCC8-AS1.
- chr8:150,584–35,093,509, 755 genes (broad region; genes not listed).
- chr8:35,254,344–35,256,605, 1 gene: AC090740.1.
- chr8:96,645,242–97,149,654, 1 gene (within-gene range 0–1): CPQ.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr12:99,985,045–99,985,619, 1 gene: AC078916.1.
- chr12:108,281,103–108,282,235, 1 gene: AC009729.1.
- chr14:106,425,359–106,443,583, 4 genes: IGHV7-40, AC244452.1, IGHVII-40-1, IGHV3-41.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,013 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:218,881,600–248,919,946, 719 genes, copy number 5 (broad region; genes not listed).
- chr2:88,811,186–88,861,563, 1 gene, copy number 7 (within-gene range 3–7): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 7: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr3:165,122,713–182,985,953, 266 genes, copy number 5 (broad region; genes not listed).
- chr8:108,443,601–108,626,767, 3 genes, copy number 5: EMC2, AC022634.1, AC022634.2.

Autosomal genes at a single copy (total copy number 1): 19,834. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
